Somatic mutation profile of tumor specimen TCGA-BR-A4J6-01A (aliquot TCGA-BR-A4J6-01A-11D-A25D-08) from TCGA case TCGA-BR-A4J6, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 69.2 years (25,279 days).
Specimen TCGA-BR-A4J6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c6d355bc-b144-4336-98fe-df95ec42738b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-A4J6-10A (Blood Derived Normal), aliquot TCGA-BR-A4J6-10A-01D-A25E-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c0dea9bc-474a-42cb-8b12-3d589ab84aa6

The open-access MAF lists 36 somatic variants for this specimen: 26 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 8, Nonsense Mutation 2, Frame Shift Ins 2, In Frame Ins 1, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.100G>A p.G34R | Missense Mutation (SNP) | VAF 5/45 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913399, COSV62687911, COSV62687931, COSV62721471; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1157G>A p.G386D | Missense Mutation (SNP) | VAF 39/85 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs121912580, CM021284, COSV61684421, COSV61688134, COSV61692671; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ARID2 | c.3814C>T p.R1272* | Nonsense Mutation (SNP) | VAF 22/42 reads (52%) | catalogued as COSV57596882; called by muse, mutect2, varscan2
- CHST6 | c.377G>T p.S126I | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60001478; called by muse, mutect2, varscan2
- CIP2A | c.736G>A p.D246N | Missense Mutation (SNP) | VAF 34/151 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.988); catalogued as COSV55420866, COSV55421126; called by muse, mutect2, varscan2
- CMYA5 | c.1075C>T p.H359Y | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs1448459809; called by muse, mutect2
- DNAJC5G | c.61G>A p.V21M | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56081038; called by muse, mutect2, varscan2
- FAM131B | c.238G>A p.G80S | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV68126851; called by muse, mutect2, varscan2
- HYAL2 | c.464C>A p.S155* | Nonsense Mutation (SNP) | VAF 48/163 reads (29%) | catalogued as COSV51701560, COSV99222702; called by muse, mutect2, varscan2
- KIAA0513 | c.1172G>C p.G391A | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.817); catalogued as COSV50743646; called by muse, mutect2, varscan2
- KIF27 | c.1535T>G p.M512R | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT tolerated (0.74); PolyPhen benign (0.006); catalogued as COSV52830572; called by muse, mutect2
- MMADHC | c.751C>T p.H251Y | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.307); catalogued as COSV57574486; called by muse, mutect2, varscan2
- MUC16 | c.2153C>A p.T718N | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.192); catalogued as COSV67487640; called by muse, mutect2, varscan2
- OR13D1 | c.619G>T p.D207Y | Missense Mutation (SNP) | VAF 43/159 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV59514619; called by muse, mutect2, varscan2
- PAPPA2 | c.2245A>G p.S749G | Missense Mutation (SNP) | VAF 53/179 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62784840; called by muse, mutect2, varscan2
- RBM42 | c.220G>T p.A74S | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs1203559748, COSV52549513; called by muse, mutect2, varscan2
- RIPOR2 | c.568A>T p.M190L | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV52422784; called by muse, mutect2, varscan2
- SLC13A2 | c.1472C>A p.A491D | Missense Mutation (SNP) | VAF 54/226 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV58998062; called by muse, mutect2, varscan2
- SPTAN1 | c.8C>A p.P3Q | Missense Mutation (SNP) | VAF 47/133 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.24); catalogued as COSV63989372; called by muse, mutect2, varscan2
- STK11 | c.908T>A p.I303N | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as CD982964, COSV58822738, COSV58827536; called by muse, varscan2
- TEP1 | c.4582G>A p.A1528T | Missense Mutation (SNP) | VAF 55/191 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as rs371466757; called by muse, mutect2, varscan2
- UBR4 | c.1519G>T p.A507S | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.956); catalogued as COSV64397092; called by muse, mutect2, varscan2
- ZNF592 | c.1123G>A p.V375M | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55439018; called by muse, mutect2, varscan2
- CHD7 | c.3864_3865insTG p.A1289Wfs*5 | Frame Shift Ins (INS) | VAF 7/29 reads (24%) | called by mutect2, pindel*, varscan2*
- CLIP2 | c.1772_1774dup p.E591dup | In Frame Ins (INS) | VAF 7/32 reads (22%) | called by mutect2, pindel, varscan2
- SLC22A3 | c.760dup p.I254Nfs*37 | Frame Shift Ins (INS) | VAF 21/77 reads (27%) | called by mutect2, pindel, varscan2
- ATR | c.3090A>C p.I1030= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as COSV63390873; called by muse, mutect2
- FYN | c.252G>A p.V84= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as COSV57619574; called by muse, mutect2, varscan2
- MAMDC2 | c.1222T>C p.L408= | Silent (SNP) | VAF 33/101 reads (33%) | catalogued as COSV65860159; called by muse, mutect2, varscan2
- SALL3 | c.1974G>A p.T658= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as rs759576604, COSV73306329; called by muse, mutect2, varscan2
- TMEM201 | c.636C>T p.V212= | Silent (SNP) | VAF 38/111 reads (34%) | catalogued as COSV61052494; called by muse, mutect2, varscan2
- TTN | c.58719T>C p.D19573= (on ENST00000591111; = p.D12149= on NM_003319.4) | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as rs771650261, COSV60284792; called by muse, mutect2, varscan2
- USP51 | c.2077T>C p.L693= | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as COSV72351902; called by muse, mutect2, varscan2
- XRCC3 | c.900G>A p.R300= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as COSV57980463; called by muse, mutect2, varscan2
- KLRA1P | n.386A>G | RNA (SNP) | VAF 11/51 reads (22%) | catalogued as rs1228078763; called by muse, mutect2, varscan2
- VPS11 | c.-648G>T | 5'UTR (SNP) | VAF 15/45 reads (33%) | catalogued as COSV56184185; called by muse, mutect2, varscan2
